Somatic mutation profile of tumor specimen C3N-03797-01 (aliquot CPT0285180007) from CPTAC case C3N-03797, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 71.5 years (26,114 days).
Specimen C3N-03797-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 117e2e43-e4c0-4ebb-b04c-4c7340749c5d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03797-31 (Blood Derived Normal), aliquot CPT0285210002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/eacce1f3-6134-4422-8ca8-f0b64a46f4d7

The open-access MAF lists 91 somatic variants for this specimen: 61 protein-altering or splice-affecting, 23 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 23, Splice Site 3, Intron 3, 5'Flank 3, Frame Shift Del 1, 5'UTR 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCA4 | c.5114G>A p.R1705Q | Missense Mutation (SNP) | VAF 117/344 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.972); catalogued as rs61753021, CM003388, CM070627, COSV100932997; called by muse, mutect2, varscan2
- ANGPTL7 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 95/318 reads (30%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); catalogued as rs775409689, COSV100816141; called by muse, mutect2, varscan2
- CHD8 | c.7496C>A p.P2499H (on ENST00000646647 / NM_001170629.2; = p.P2220H on NM_020920.4) | Missense Mutation (SNP) | VAF 56/137 reads (41%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs1212151127; ClinVar: uncertain significance; called by mutect2, varscan2
- COPB2 | c.613G>A p.G205S | Missense Mutation (SNP) | VAF 45/121 reads (37%) | SIFT tolerated (0.2); PolyPhen probably damaging (0.99); catalogued as COSV60812940; called by muse, mutect2, varscan2
- CSGALNACT2 | c.107C>T p.P36L | Missense Mutation (SNP) | VAF 108/230 reads (47%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as rs1183173383; called by muse, mutect2, varscan2
- DMD | c.5288G>T p.R1763L | Missense Mutation (SNP) | VAF 61/102 reads (60%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.649); catalogued as rs398123982, COSV63757525; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- DOCK5 | c.3659G>A p.R1220H | Missense Mutation (SNP) | VAF 70/255 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.647); catalogued as rs778275685, COSV52403638; called by muse, mutect2, varscan2
- FAM13C | c.248G>C p.S83T | Missense Mutation (SNP) | VAF 27/342 reads (8%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0); catalogued as COSV53249750; called by muse, mutect2
- FBN2 | c.2779G>A p.A927T | Missense Mutation (SNP) | VAF 186/612 reads (30%) | SIFT deleterious (0.03); PolyPhen benign (0.41); catalogued as rs863223559; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- GRIN2A | c.995A>T p.H332L | Missense Mutation (SNP) | VAF 58/345 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.018); catalogued as COSV58043707; called by muse, mutect2, varscan2
- H2BW1 | c.197G>A p.R66H | Missense Mutation (SNP) | VAF 102/148 reads (69%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.781); catalogued as rs781962912, COSV54220644; called by muse, mutect2, varscan2
- HID1 | c.1165G>A p.V389M | Missense Mutation (SNP) | VAF 59/102 reads (58%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.597); catalogued as rs748439446; called by muse, mutect2, varscan2
- HINFP | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 85/412 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs575006452, COSV100640808; called by muse, mutect2, varscan2
- IRF2BP2 | c.875G>A p.G292E | Missense Mutation (SNP) | VAF 81/202 reads (40%) | SIFT tolerated (0.23); PolyPhen benign (0.086); catalogued as rs778815968; called by muse, mutect2, varscan2
- JAG2 | c.1723C>T p.R575C | Missense Mutation (SNP) | VAF 166/307 reads (54%) | SIFT deleterious (0); PolyPhen possibly damaging (0.724); catalogued as rs1375288713; called by muse, mutect2, varscan2
- LSM12 | c.368C>T p.T123I | Missense Mutation (SNP) | VAF 54/170 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as rs1263919388; called by muse, mutect2, varscan2
- PKHD1L1 | c.8131G>A p.G2711S | Missense Mutation (SNP) | VAF 74/298 reads (25%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.725); catalogued as rs1201050500, COSV65739671; called by muse, mutect2, varscan2
- RADX | c.661C>T p.L221F | Missense Mutation (SNP) | VAF 28/46 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs774847325; called by muse, mutect2, varscan2
- RB1 | c.2104C>A p.Q702K | Missense Mutation (SNP) | VAF 114/250 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM030513, CM127815, COSV57307527, COSV57329700; called by muse, varscan2
- SETD2 | c.1820del p.P607Lfs*15 | Frame Shift Del (DEL) | VAF 37/130 reads (28%) | catalogued as COSV100339824; called by mutect2, pindel, varscan2
- SLC1A3 | c.1450G>A p.V484I | Missense Mutation (SNP) | VAF 133/463 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as rs549164007, COSV54321178; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC22A2 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 30/126 reads (24%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.982); catalogued as rs1017655480; called by muse, mutect2, varscan2
- THEM6 | c.476C>T p.S159L | Missense Mutation (SNP) | VAF 53/152 reads (35%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.767); catalogued as rs1554642559; called by muse, mutect2, varscan2
- TNXB | c.1697G>A p.R566H | Missense Mutation (SNP) | VAF 248/744 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.011); catalogued as rs1425189838; called by muse, mutect2, varscan2
- TP53 | c.766A>C p.T256P | Missense Mutation (SNP) | VAF 163/253 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs587781433, CD120857, CM102355, COSV52801994, COSV52979358, COSV52987324, COSV53050299; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTC6 | c.2453C>A p.P818H | Missense Mutation (SNP) | VAF 32/67 reads (48%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); catalogued as rs1466826746; called by muse, mutect2, varscan2
- UNC5C | c.1250C>T p.S417L | Missense Mutation (SNP) | VAF 31/104 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as rs202087388; called by muse, mutect2, varscan2
- WFDC9 | c.185G>A p.R62H | Missense Mutation (SNP) | VAF 19/106 reads (18%) | SIFT tolerated (0.55); PolyPhen benign (0); catalogued as rs779633205, COSV58097251; called by muse, mutect2, varscan2
- ZNF648 | c.854G>A p.G285E | Missense Mutation (SNP) | VAF 9/284 reads (3%) | SIFT tolerated (0.06); PolyPhen benign (0.118); catalogued as COSV60570863; called by muse, mutect2
- ABCF1 | c.183G>C p.E61D | Missense Mutation (SNP) | VAF 70/239 reads (29%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ADAMTS20 | c.1675T>C p.W559R | Missense Mutation (SNP) | VAF 54/283 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ANKRD12 | c.5204T>G p.M1735R | Missense Mutation (SNP) | VAF 61/186 reads (33%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ANO8 | c.1673A>C p.E558A | Missense Mutation (SNP) | VAF 3/26 reads (12%) | SIFT tolerated (0.05); PolyPhen benign (0.437); called by muse, mutect2
- CFAP69 | c.2617A>G p.I873V | Missense Mutation (SNP) | VAF 30/107 reads (28%) | SIFT tolerated (0.54); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.5167G>A p.D1723N | Missense Mutation (SNP) | VAF 131/396 reads (33%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); called by muse, mutect2, varscan2
- GCNT2 | c.821C>T p.A274V | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT tolerated (1); PolyPhen benign (0.023); called by muse, mutect2, varscan2
- GPR68 | c.554_556del p.I185del | In Frame Del (DEL) | VAF 108/239 reads (45%) | called by mutect2, pindel, varscan2
- GUCY2D | c.2813C>T p.P938L | Missense Mutation (SNP) | VAF 130/202 reads (64%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- IL15RA | c.200C>T p.A67V | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- ITGA1 | c.2652C>G p.I884M | Missense Mutation (SNP) | VAF 12/65 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- MIA3 | c.2853G>C p.L951F | Missense Mutation (SNP) | VAF 50/148 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.441); called by muse, mutect2, varscan2
- MLPH | c.1186G>T p.V396F | Missense Mutation (SNP) | VAF 75/263 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.926); called by muse, mutect2
- MTF1 | c.991-1G>A p.X331_splice | Splice Site (SNP) | VAF 39/109 reads (36%) | called by muse, mutect2, varscan2
- MUC12 | c.1513C>A p.H505N (on ENST00000379442; = p.H362N on NM_001164462.1) | Missense Mutation (SNP) | VAF 102/336 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.39); called by muse, mutect2, varscan2
- NT5C1B | c.1441A>T p.T481S (on ENST00000359846 / NM_001199086.2; = p.T421S on NM_033253.4) | Missense Mutation (SNP) | VAF 10/186 reads (5%) | SIFT tolerated (0.42); PolyPhen benign (0.158); called by muse, mutect2
- OTOG | c.5266C>T p.P1756S | Missense Mutation (SNP) | VAF 28/106 reads (26%) | SIFT tolerated (0.4); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- PLA2G4A | c.1585G>T p.D529Y | Missense Mutation (SNP) | VAF 68/230 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.744); called by muse, mutect2, varscan2
- PPIL2 | c.808G>A p.V270M | Missense Mutation (SNP) | VAF 113/224 reads (50%) | SIFT tolerated (0.05); PolyPhen benign (0.418); called by muse, mutect2, varscan2
- RBBP6 | c.3518C>A p.T1173N | Missense Mutation (SNP) | VAF 64/212 reads (30%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.193); called by muse, mutect2, varscan2
- SIGLEC14 | c.554T>A p.L185H | Missense Mutation (SNP) | VAF 67/195 reads (34%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- SIPA1L1 | c.367A>G p.S123G | Missense Mutation (SNP) | VAF 17/197 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.011); called by muse, mutect2
- SPATA17 | c.680C>G p.P227R | Missense Mutation (SNP) | VAF 60/195 reads (31%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- SVIP | c.54+2T>A p.X18_splice | Splice Site (SNP) | VAF 68/252 reads (27%) | called by muse, mutect2, varscan2
- TEAD1 | c.454G>A p.G152R | Missense Mutation (SNP) | VAF 73/263 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0.03); called by muse, mutect2, varscan2
- TMEM259 | c.1000+1G>A p.X334_splice | Splice Site (SNP) | VAF 20/67 reads (30%) | called by muse, mutect2, varscan2
- TPH2 | c.884T>A p.V295E | Missense Mutation (SNP) | VAF 190/519 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- VWA5B1 | c.737G>C p.R246P | Missense Mutation (SNP) | VAF 49/139 reads (35%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- WWC1 | c.307G>A p.A103T | Missense Mutation (SNP) | VAF 91/296 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.503); called by muse, mutect2, varscan2
- ZBED8 | c.577C>G p.R193G | Missense Mutation (SNP) | VAF 69/224 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); called by mutect2, varscan2
- ZNF518A | c.4235C>T p.P1412L | Missense Mutation (SNP) | VAF 12/27 reads (44%) | SIFT deleterious (0); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- ZYG11B | c.583A>T p.N195Y | Missense Mutation (SNP) | VAF 50/138 reads (36%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ANK1 | c.2883G>A p.T961= | Silent (SNP) | VAF 124/359 reads (35%) | catalogued as rs1473569323; called by muse, mutect2, varscan2
- ARHGAP32 | c.4938C>A p.V1646= (on ENST00000310343 / NM_001378025.1; = p.V1297= on NM_014715.4) | Silent (SNP) | VAF 59/214 reads (28%) | catalogued as rs1258553275; called by muse, mutect2, varscan2
- CACNA1H | c.5841G>A p.P1947= | Silent (SNP) | VAF 19/94 reads (20%) | catalogued as rs561421034; called by muse, mutect2
- CYP2C9 | c.1059C>T p.H353= | Silent (SNP) | VAF 113/235 reads (48%) | catalogued as rs369488415; called by muse, mutect2, varscan2
- EIF3B | c.285G>A p.S95= | Silent (SNP) | VAF 80/334 reads (24%) | catalogued as rs1343448885; called by muse, mutect2, varscan2
- KLHDC2 | c.786C>T p.G262= | Silent (SNP) | VAF 72/142 reads (51%) | catalogued as rs749990499; called by muse, mutect2, varscan2
- LETM2 | c.429C>T p.D143= (on ENST00000379957 / NM_001286819.2; = p.D96= on NM_144652.3) | Silent (SNP) | VAF 39/148 reads (26%) | catalogued as rs369104625; called by muse, mutect2, varscan2
- MASP1 | c.1875G>A p.V625= | Silent (SNP) | VAF 118/413 reads (29%) | called by muse, mutect2, varscan2
- MEX3B | c.1437G>A p.G479= | Silent (SNP) | VAF 23/55 reads (42%) | called by muse, mutect2, varscan2
- NIPSNAP2 | c.486C>G p.L162= | Silent (SNP) | VAF 85/207 reads (41%) | called by muse, mutect2, varscan2
- OR6C75 | c.138C>T p.L46= | Silent (SNP) | VAF 37/107 reads (35%) | called by muse, mutect2, varscan2
- PALM2AKAP2 | c.993C>T p.D331= (on ENST00000374531 / NM_001037293.2; = p.D363= on NM_053016.6) | Silent (SNP) | VAF 99/295 reads (34%) | catalogued as rs776106715, COSV57111631; called by muse, mutect2, varscan2
- PLXNB1 | c.558C>T p.T186= | Silent (SNP) | VAF 29/86 reads (34%) | catalogued as rs771827169; called by muse, mutect2, varscan2
- PROX2 | c.1551C>T p.R517= (on ENST00000556489 / NM_001243007.1; = p.R290= on NM_001080408.2) | Silent (SNP) | VAF 41/122 reads (34%) | called by muse, mutect2, varscan2
- RPTN | c.2124G>A p.E708= | Silent (SNP) | VAF 105/303 reads (35%) | catalogued as rs767865532; called by muse, mutect2, varscan2
- SEC23B | c.496C>T p.L166= | Silent (SNP) | VAF 144/535 reads (27%) | called by muse, mutect2, varscan2
- SLC5A9 | c.282C>T p.I94= | Silent (SNP) | VAF 111/285 reads (39%) | catalogued as rs760758292; called by muse, mutect2, varscan2
- SPEG | c.6564C>T p.T2188= | Silent (SNP) | VAF 125/356 reads (35%) | called by muse, mutect2, varscan2
- SPIRE2 | c.39C>A p.G13= | Silent (SNP) | VAF 5/89 reads (6%) | called by muse, mutect2
- TENM3 | c.6084C>G p.T2028= | Silent (SNP) | VAF 30/205 reads (15%) | called by muse, mutect2, varscan2
- TLE1 | c.471C>T p.P157= | Silent (SNP) | VAF 41/160 reads (26%) | catalogued as rs536506845; called by muse, mutect2, varscan2
- UGT2B4 | c.63G>T p.G21= | Silent (SNP) | VAF 23/83 reads (28%) | catalogued as COSV59319868; called by muse, mutect2, varscan2
- URB1 | c.3570G>A p.T1190= | Silent (SNP) | VAF 92/374 reads (25%) | catalogued as rs1203730177; called by muse, varscan2
- ANKRD42 | c.138+12C>T | Intron (SNP) | VAF 38/123 reads (31%) | catalogued as rs1356540233; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499362 A>G | 5'Flank (SNP) | VAF 53/223 reads (24%) | catalogued as rs1366102415; called by muse, mutect2, varscan2
- LSP1 | c.54-13304G>A | Intron (SNP) | VAF 7/189 reads (4%) | called by muse, mutect2
- MROH8 | chr20:37160116 C>T | 5'Flank (SNP) | VAF 27/96 reads (28%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159198 G>A | 5'Flank (SNP) | VAF 36/124 reads (29%) | catalogued as rs115157005; called by muse, mutect2, varscan2
- SYT8 | c.-13G>A | 5'UTR (SNP) | VAF 124/339 reads (37%) | called by muse, mutect2, varscan2
- TBC1D8B | c.1838-753G>A | Intron (SNP) | VAF 20/31 reads (65%) | catalogued as rs754898619; called by muse, mutect2, varscan2
